MMRF case MMRF_2314 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/96d05ad0-f794-48b8-811d-9506aecb5e26

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 59 years; Vital status: Dead; Days to death: 96 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.6 years (21,777 days); ISS stage: II; Days to last known disease status: 96 days; Days to last follow up: 96 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 90 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 90 days.

Follow-up (2 entries)
- Days to follow up: 1 day; ECOG performance status: 3.
- Follow-up contact recording only the day: day 96.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Serum Free Immunoglobulin Light Chain, Kappa 34.7 mg/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.097 mg/dL.
- Hemoglobin 7.94 mmol/L.
- M Protein 3.54 g/dL.
- C-Reactive Protein 0.31 mg/dL.
- Absolute Neutrophil 2.74 ×10⁹/L.
- Glucose 4.68 mmol/L.
- Immunoglobulin A 0.207 g/L.
- Lactate Dehydrogenase 3.73 µkat/L.
- Platelets 268 ×10⁹/L.
- Immunoglobulin G 56.3 g/L.
- Leukocytes 6.54 ×10⁹/L.
- Albumin 39 g/L.
- Calcium 2.65 mmol/L.
- Beta 2 Microglobulin 4.35 µg/mL.
- Immunoglobulin M 0.098 g/L.
- Total Protein 10 g/dL.
- Creatinine 75.1 µmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 183 cm.

Biospecimens (2 samples)
- Sample MMRF_2314_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2314_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
